Somatic mutation profile of tumor specimen BA2791D (aliquot aq-BA2791D) from BEATAML1.0 case 2573, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.0 years (9,848 days).
Specimen BA2791D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb50d0b0-fec4-43b1-8fb4-c7310c1f16f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2703D (Solid Tissue Normal), aliquot aq-BA2703D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0db0f8e8-bb3e-421d-8959-723599e14bfe

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 2, RNA 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.4176C>A p.S1392R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1235699222; called by muse, mutect2
- CHST4 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58296387, COSV58297588; called by muse, mutect2
- DCAF4L1 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 47/126 reads (37%) | catalogued as COSV60788414; called by muse, mutect2, varscan2
- GLRB | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs975522417; called by muse, mutect2, varscan2
- KRT27 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs141587650; called by muse, mutect2, varscan2
- LRP2 | c.11878C>G p.L3960V | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV55550637; called by muse, mutect2
- SPTBN2 | c.2918G>C p.W973S | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100020847; called by muse, mutect2, varscan2
- STK31 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1282523650, COSV63454154; called by muse, mutect2
- ABCC3 | c.3451T>C p.F1151L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- APOA4 | c.1025T>C p.F342S | Missense Mutation (SNP) | VAF 142/449 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CADM4 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2
- CASC3 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.418); called by muse, mutect2
- EFCAB14 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- GREB1L | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2
- HIP1R | c.2175C>A p.C725* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- KRT5 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NOS1AP | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RASA2 | c.2504C>A p.A835E | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2
- SPATA1 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SPEG | c.3690C>A p.S1230R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRABD2B | c.108G>T p.R36S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ZNF823 | c.917G>T p.C306F (on ENST00000341191 / NM_001297610.2; = p.C262F on NM_017507.2) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- COL6A6 | c.4830C>T p.P1610= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs533372119, COSV62025626; called by muse, mutect2
- GABRB2 | c.1062C>T p.R354= | Silent (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- NFKBIE | c.303G>T p.P101= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- PCDHA3 | c.201G>A p.A67= | Silent (SNP) | VAF 72/444 reads (16%) | catalogued as COSV65369622; called by muse, mutect2, varscan2
- PML | c.795C>A p.V265= | Silent (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- TFB2M | c.591T>C p.S197= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs532418928; called by muse, mutect2, varscan2
- C17orf107 | c.*674C>A | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- DNM1P47 | n.826C>T | RNA (SNP) | VAF 81/288 reads (28%) | catalogued as rs762050306; called by muse, mutect2, varscan2
- METTL16 | chr17:2415344 C>A | 3'Flank (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
